Somatic mutation profile of tumor specimen TCGA-OR-A5KO-01A (aliquot TCGA-OR-A5KO-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KO, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 40.0 years (14,606 days).
Specimen TCGA-OR-A5KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7304cfe-ed44-420f-a8aa-155179c98c7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KO-10A (Blood Derived Normal), aliquot TCGA-OR-A5KO-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4355175b-9960-4377-a6da-9f2b191d7c5f

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 79/93 reads (85%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.178); catalogued as rs775714953, COSV53675149; called by muse, mutect2, varscan2
- DDR1 | c.2618C>T p.P873L (on ENST00000324771; = p.P836L on NM_001954.4) | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779035359, COSV100241448; called by muse, mutect2, varscan2
- MANBA | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs777157327; called by muse, mutect2, varscan2
- SMARCAL1 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 72/82 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172616375; called by muse, mutect2, varscan2
- ZNF546 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61257273; called by muse, mutect2, varscan2
- ADAMTS18 | c.1421G>T p.W474L | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC171 | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDH12 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 142/361 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- CHST9 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HCAR1 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 64/70 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-G | c.994T>C p.W332R | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPG2 | c.6301C>G p.R2101G | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PAPOLA | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PDILT | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLITRK5 | c.2867_2874del p.S956Ifs*13 | Frame Shift Del (DEL) | VAF 18/19 reads (95%) | called by mutect2, varscan2
- ZNF77 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF774 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.6078T>C p.F2026= | Silent (SNP) | VAF 33/38 reads (87%) | called by muse, mutect2, varscan2
- CYP21A2 | c.405C>T p.S135= | Silent (SNP) | VAF 162/359 reads (45%) | called by muse, mutect2, varscan2
- FER1L6 | c.4773G>A p.R1591= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as rs751596489, COSV67552889; called by muse, mutect2, varscan2
- JHY | c.1665G>T p.T555= | Silent (SNP) | VAF 82/90 reads (91%) | called by muse, varscan2
- KMT2D | c.1914A>C p.P638= | Silent (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- SMC1A | c.2241C>G p.R747= | Silent (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- TRAF3IP2 | c.366C>T p.V122= | Silent (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
